Somatic mutation profile of tumor specimen BA2777D (aliquot aq-BA2777D) from BEATAML1.0 case 2258, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.1 years (22,310 days).
Specimen BA2777D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3537d99-2d66-407e-aa51-d66a37b5192d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2732D (Solid Tissue Normal), aliquot aq-BA2732D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0a62025-3bdb-4383-aceb-40c8808feecd

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Frame Shift Ins 3, Intron 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 118/640 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP13A1 | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs375254274; called by muse, mutect2, varscan2
- BMP4 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs1435675398; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 21/96 reads (22%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- OPRPN | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.95); catalogued as rs780507864; called by muse, mutect2, varscan2
- PPP2R3A | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs199925843; called by muse, mutect2, varscan2
- RYR3 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs1264434931, COSV66776349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC43A2 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs199501622; called by muse, varscan2
- SMC3 | c.1982G>C p.R661P | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62421429, COSV62423179; called by muse, mutect2, varscan2
- THBS4 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs34249634; called by muse, mutect2, varscan2
- TSKS | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs773071788; called by muse, varscan2
- ZC3H7A | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs190287463; called by muse, varscan2
- ABCB9 | c.53T>A p.I18N | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ARID2 | c.109dup p.I37Nfs*29 | Frame Shift Ins (INS) | VAF 61/124 reads (49%) | called by mutect2, varscan2
- DOT1L | c.1652dup p.L551Ffs*3 | Frame Shift Ins (INS) | VAF 54/171 reads (32%) | called by mutect2, pindel, varscan2
- NEK5 | c.1937A>C p.Q646P | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, varscan2
- CDX1 | c.-32G>A | 5'UTR (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- GRINA | c.693+64C>A | Intron (SNP) | VAF 4/35 reads (11%) | catalogued as rs781986924; called by muse, mutect2
- INPP5K | c.*63G>T | 3'UTR (SNP) | VAF 3/31 reads (10%) | catalogued as rs981029293; called by muse, mutect2
- SIRT7 | c.94-12G>T | Intron (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
